Gene-level copy-number profile of tumor specimen TCGA-85-8352-01A from TCGA case TCGA-85-8352, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.9 years (24,788 days).
Specimen TCGA-85-8352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f4c254a0-3622-47cf-aa32-a7159d221e44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8352-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d3600b1-2a81-4f6a-81af-a960b2c8c134

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,236; copy number 2: 25,592; copy number 3: 18,016; copy number 4: 10,384; copy number 5: 3,641; copy number 6: 285; copy number 7: 116; copy number 8: 288; copy number 9: 43; copy number 11: 42; copy number 12: 2; copy number 13: 7; copy number 14: 70; copy number 18: 28; copy number 20: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8352-01A-31D-2322-01): tumor purity 0.93, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,585 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,414,931–245,709,432, 2,532 genes, copy number 5–8 (broad region; genes not listed).
- chr1:246,724,409–248,919,946, 119 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:14,530,941–24,413,292, 146 genes, copy number 6–18 (broad region; genes not listed).
- chr2:49,202,126–63,087,322, 186 genes, copy number 5 (broad region; genes not listed).
- chr2:63,108,118–63,119,542, 2 genes, copy number 5: RPL27P5, DBIL5P2.
- chr3:53,858,994–61,251,459, 91 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:83,924,157–84,051,419, 3 genes, copy number 5: AC092825.1, SRRM1P2, AC117464.1.
- chr3:172,425,850–172,604,006, 6 genes, copy number 5: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr5:58,198–5,140,119, 109 genes, copy number 6 (broad region; genes not listed).
- chr5:5,142,138–5,176,214, 1 gene, copy number 6 (within-gene range 4–6): AC022424.1.
- chr5:20,158,662–45,895,970, 356 genes, copy number 5–7 (broad region; genes not listed).
- chr5:52,930,606–52,990,278, 1 gene, copy number 5 (within-gene range 4–5): AC025180.1.
- chr5:53,024,924–53,035,884, 1 gene, copy number 5 (within-gene range 2–5): AC008966.3.
- chr5:58,969,038–60,522,120, 1 gene, copy number 5 (within-gene range 2–11): PDE4D.
- chr5:59,528,861–62,777,263, 45 genes, copy number 5–11: NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1.
- chr6:48,213,604–50,847,619, 33 genes, copy number 5: RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B.
- chr6:76,446,988–77,097,788, 6 genes, copy number 5–11 (within-gene range 4–11): RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1.
- chr6:132,271,982–140,898,381, 164 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:85,381,118–105,399,308, 433 genes, copy number 5–8 (broad region; genes not listed).
- chr8:135,742,343–139,127,953, 16 genes, copy number 5: RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr9:35,360,540–37,592,604, 89 genes, copy number 7–18 (broad region; genes not listed).
- chr10:35,778,302–38,150,293, 40 genes, copy number 5: PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A.
- chr10:38,137,337–38,212,417, 3 genes, copy number 5 (within-gene range 3–5): AL117339.3, AL117339.1, CCNYL4.
- chr11:67,289,300–71,252,577, 137 genes, copy number 7–20 (within-gene range 3–20) (broad region; genes not listed).
- chr17:14,235,673–15,563,595, 32 genes, copy number 7: CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1, RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2.
- chr17:15,574,019–15,574,198, 1 gene, copy number 7: SNORA74.
- chr17:52,390,515–54,670,420, 14 genes, copy number 5: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1.
- chr20:50,840,615–51,905,030, 18 genes, copy number 8–13: TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P.

Autosomal genes at a single copy (total copy number 1): 1,236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
